Somatic mutation profile of tumor specimen MMRF_1307_1_BM_CD138pos (aliquot MMRF_1307_1_BM_CD138pos_T1_TSE61_l00109) from MMRF case MMRF_1307, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.1 years (27,047 days).
Specimen MMRF_1307_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 127f8024-9748-448b-ac2f-da4fc83cea28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1307_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1307_1_PB_Whole_C2_TSE61_l00115; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64bef0a4-af65-4b9a-81e0-23726ab6d85e

The open-access MAF lists 84 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 28, Missense Mutation 26, Silent 9, Intron 5, 3'Flank 4, Splice Region 3, 5'UTR 3, RNA 2, Frame Shift Del 2, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B4 | c.3426C>G p.I1142M | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52713148; called by muse, mutect2
- CDH6 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.93); catalogued as COSV99419565; called by muse, mutect2, varscan2
- CNNM1 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs140364515; called by muse, mutect2, varscan2
- CNTRL | c.2235G>T p.E745D | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs776242562; called by muse, mutect2, varscan2
- COL4A2 | c.1783G>A p.G595S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1328304940; called by muse, mutect2
- DIS3 | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66708362; called by mutect2, varscan2
- DLK1 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.988); catalogued as COSV57992425; called by muse, mutect2, varscan2
- DNAI2 | c.1615G>A p.V539I | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs199817659; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FUT5 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201842894; called by muse, mutect2, varscan2
- HHATL | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.48); PolyPhen benign (0.033); catalogued as rs918851737, COSV55132397; called by muse, mutect2, varscan2
- LILRB5 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as rs563580680; called by muse, mutect2, varscan2
- PJA1 | c.1127G>A p.R376H (on ENST00000361478 / NM_145119.4; = p.R188H on NM_022368.5) | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT tolerated (0.08); PolyPhen benign (0.379); catalogued as rs189968793, COSV64053644; called by muse, mutect2, varscan2
- PLEKHA4 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781033749, COSV54364746; called by muse, mutect2, varscan2
- RAI14 | c.991A>G p.T331A | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs770064831, COSV54293798; called by muse, mutect2, varscan2
- URM1 | c.186C>T p.S62= | Splice Region (SNP) | VAF 15/59 reads (25%) | catalogued as rs766952146; called by muse, mutect2, varscan2
- ADAM2 | c.269A>T p.N90I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ALX1 | c.718A>C p.M240L | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CCDC171 | c.2176T>C p.S726P | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CHD2 | c.3646del p.Q1216Rfs*4 | Frame Shift Del (DEL) | VAF 32/76 reads (42%) | called by mutect2, varscan2
- CHD5 | c.3559C>A p.Q1187K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- DNAJB12 | c.1186A>G p.S396G (on ENST00000338820; = p.S362G on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- DPP4 | c.419G>T p.R140M | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- FBXL2 | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- INTS1 | c.3881A>T p.H1294L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- MBNL3 | c.715C>A p.Q239K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2
- MTMR2 | c.25_26del p.L10Wfs*50 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | called by pindel, varscan2
- PDCD1LG2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PKD2L1 | c.2007G>A p.R669= | Splice Region (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- PLEKHF1 | c.4G>A p.V2M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); called by muse, mutect2
- TAAR2 | c.257C>T p.A86V (on ENST00000367931 / NM_001033080.1; = p.A41V on NM_014626.3) | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- TENT5C | c.413A>G p.Y138C | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TPX2 | c.1689G>T p.V563= | Splice Region (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- BNC2 | c.2064G>A p.V688= | Silent (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- CCNB3 | c.3258C>T p.T1086= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs781802833; called by muse, mutect2, varscan2
- CRACR2B | c.492G>A p.L164= | Silent (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- CREBBP | c.4356G>A p.E1452= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV99270841; called by muse, mutect2, varscan2
- DLGAP3 | c.924G>A p.S308= | Silent (SNP) | VAF 40/71 reads (56%) | catalogued as rs753640455, COSV52398292; called by muse, mutect2, varscan2
- FAT4 | c.6621C>A p.V2207= | Silent (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- IRF4 | c.1137A>G p.P379= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV101110977; called by muse, mutect2, varscan2
- SPTBN5 | c.4284G>T p.L1428= | Silent (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- WNT10B | c.360C>T p.S120= | Silent (SNP) | VAF 31/52 reads (60%) | catalogued as rs1342916502; called by muse, mutect2, varscan2
- ABCB5 | c.982-33G>A | Intron (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- ABI3 | chr17:49210633 T>G | 5'Flank (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-10461G>A | Intron (SNP) | VAF 28/65 reads (43%) | catalogued as rs1487976021; called by muse, mutect2, varscan2
- AL133216.2 | n.5896G>T | RNA (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- ALKBH2 | c.-121T>C | 5'UTR (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- ATP13A4 | c.*276G>T | 3'UTR (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- AXL | c.-24A>C | 5'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2
- CCDC113 | c.*1395A>G | 3'UTR (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- CDS2 | c.*963T>C | 3'UTR (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- CHST9 | chr18:26911788 C>T | 3'Flank (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- CLN6 | c.*521T>C | 3'UTR (SNP) | VAF 44/79 reads (56%) | called by muse, mutect2, varscan2
- EFNA5 | c.*3272C>A | 3'UTR (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- ERAP1 | c.*1694A>C | 3'UTR (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2
- ERBB4 | c.*4194A>C | 3'UTR (SNP) | VAF 45/79 reads (57%) | called by muse, mutect2, varscan2
- EXPH5 | c.*2267C>T | 3'UTR (SNP) | VAF 5/64 reads (8%) | catalogued as rs1392734763; called by muse, mutect2
- FHDC1 | c.*1574G>T | 3'UTR (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- GALNT9 | c.419+8677C>T | Intron (SNP) | VAF 4/62 reads (6%) | catalogued as rs1317717345; called by muse, mutect2
- GAPVD1 | c.*257A>C | 3'UTR (SNP) | VAF 78/116 reads (67%) | called by muse, mutect2, varscan2
- GKAP1 | c.*118C>G | 3'UTR (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- IKZF2 | chr2:213004005 C>A | 3'Flank (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- IKZF4 | c.*2284C>T | 3'UTR (SNP) | VAF 39/88 reads (44%) | catalogued as rs1027566650; called by muse, mutect2, varscan2
- ITPR2 | c.*3000A>G | 3'UTR (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- KCNJ3 | c.*973T>C | 3'UTR (SNP) | VAF 27/50 reads (54%) | called by muse, mutect2, varscan2
- KLF12 | c.*7506G>A | 3'UTR (SNP) | VAF 22/24 reads (92%) | catalogued as rs1362066945; called by muse, mutect2, varscan2
- LINC01020 | n.1646C>T | RNA (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- MEPCE | c.*396T>G | 3'UTR (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2
- MIR6073 | chr11:15967499 A>G | 3'Flank (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- PBX1 | c.*2990T>G | 3'UTR (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2
- RAB3IP | c.*2010_*2021del | 3'UTR (DEL) | VAF 8/51 reads (16%) | called by pindel, varscan2
- RAB4B | c.*168C>G | 3'UTR (SNP) | VAF 37/78 reads (47%) | called by muse, mutect2, varscan2
- RBBP9 | c.*1235C>T | 3'UTR (SNP) | VAF 12/30 reads (40%) | catalogued as rs1471255123; called by muse, mutect2, varscan2
- SLTM | c.-23C>T | 5'UTR (SNP) | VAF 4/14 reads (29%) | catalogued as rs370700130; called by muse, mutect2
- SNN | c.*238C>T | 3'UTR (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- SRFBP1 | c.*295T>A | 3'UTR (SNP) | VAF 20/32 reads (63%) | catalogued as rs1241046089; called by muse, varscan2
- THBS2 | c.*904C>T | 3'UTR (SNP) | VAF 36/87 reads (41%) | catalogued as rs1275247560; called by muse, mutect2, varscan2
- TTN | c.10360+4273A>C | Intron (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- UBL3 | c.*2257del | 3'UTR (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel
- VANGL1 | chr1:115692792 C>G | 3'Flank (SNP) | VAF 29/35 reads (83%) | called by muse, mutect2, varscan2
- VPS53 | c.*402_*409del | 3'UTR (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel
- XRN1 | c.*1239T>G | 3'UTR (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2
- ZBBX | c.*471T>A | 3'UTR (SNP) | VAF 12/34 reads (35%) | catalogued as rs1247767351; called by muse, mutect2, varscan2
- ZNF107 | c.-204-724del | Intron (DEL) | VAF 26/51 reads (51%) | called by mutect2, pindel, varscan2
- ZNF853 | c.*421G>T | 3'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
